Somatic mutation profile of tumor specimen TARGET-10-PARKFN-09A (aliquot TARGET-10-PARKFN-09A-01D) from TARGET case TARGET-10-PARKFN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,099 days).
Specimen TARGET-10-PARKFN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03ead5e4-6901-4102-bf51-8a2cc74b6d68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKFN-10A (Blood Derived Normal), aliquot TARGET-10-PARKFN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a117a6e-c1df-48af-a465-18a041e4d867

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 4, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP63 | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 42/92 reads (46%) | catalogued as rs941268998, COSV53220156; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NHS | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66274519; called by muse, mutect2, varscan2
- RBMXL2 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.556); catalogued as rs372863726; called by muse, mutect2, varscan2
- TDG | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776409591, COSV57166577; called by muse, mutect2
- FLT3 | c.1766_1775delinsCGCCGGG p.Y589_V592delinsSPG | In Frame Del (DEL) | VAF 16/37 reads (43%) | called by pindel, varscan2*
- SPI1 | c.669G>A p.M223I | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBN3 | c.4641G>A p.P1547= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs754106480; called by muse, mutect2, varscan2
- HTR2C | c.642C>T p.F214= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs368641796, COSV52202768, COSV52205141; called by muse, mutect2, varscan2
- MLLT6 | c.825C>A p.S275= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- WDR59 | c.2685G>A p.G895= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- ACADM | c.287-300dup | Intron (INS) | VAF 11/26 reads (42%) | called by mutect2, pindel, varscan2
